Somatic mutation profile of tumor specimen TARGET-10-PARVAK-09A (aliquot TARGET-10-PARVAK-09A-01D) from TARGET case TARGET-10-PARVAK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,198 days).
Specimen TARGET-10-PARVAK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ea437b8-6a61-4537-a31e-335fd4b905da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARVAK-14A (Bone Marrow Normal), aliquot TARGET-10-PARVAK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd449d93-9c72-4b3b-9a8b-7fc120e3e4b4

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOL6 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1339159022; called by muse, mutect2, varscan2
- CTCF | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567610917, COSV50461678; ClinVar: uncertain significance; called by muse, mutect2
- UPF1 | c.1598C>T p.P533L (on ENST00000599848 / NM_001297549.2; = p.P522L on NM_002911.4) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568279022, COSV53194164; called by muse, mutect2
- ASIC3 | c.1539C>T p.A513= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs370089221, COSV52522746; called by muse, mutect2, varscan2
- BAZ2B | c.132A>G p.T44= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- CBX6 | c.909C>T p.S303= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs761801572; called by muse, mutect2, varscan2
- TSG101 | c.-124A>T | 5'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
